Somatic mutation profile of tumor specimen TCGA-EX-A1H6-01B (aliquot TCGA-EX-A1H6-01B-11D-A22X-09) from TCGA case TCGA-EX-A1H6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G1; Age at diagnosis: 38.9 years (14,214 days).
Specimen TCGA-EX-A1H6-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c9ee39d-aa46-487c-852a-fe76df9d1d09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EX-A1H6-10A (Blood Derived Normal), aliquot TCGA-EX-A1H6-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af4322c2-9ecb-4dc5-8018-e7b2420a4c7c

The open-access MAF lists 112 somatic variants for this specimen: 80 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 30, Nonsense Mutation 6, Frame Shift Ins 1, Splice Site 1, RNA 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGB3 | c.1929-1G>A p.X643_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | catalogued as rs750257554, COSV60688247; ClinVar: likely pathogenic; called by muse, mutect2
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACOX3 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149218868; called by muse, mutect2, varscan2
- ACP4 | c.1217G>C p.S406T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.052); catalogued as COSV54516248; called by muse, mutect2, varscan2
- ADAM9 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1186085450, COSV65958880; called by muse, mutect2, varscan2
- ADAMTS16 | c.2185G>C p.D729H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV56979733; called by muse, mutect2, varscan2
- AFTPH | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV53216064; called by muse, mutect2, varscan2
- AGL | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs757347826, COSV54048566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP8L | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs570266491, COSV68472907; called by muse, mutect2, varscan2
- ASAP1 | c.2143G>C p.D715H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.928); catalogued as COSV63044899; called by muse, mutect2, varscan2
- ATP5F1D | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53066486; called by muse, mutect2, varscan2
- ATP6V0A4 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100023677; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3266C>T p.S1089F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62572303; called by muse, mutect2, varscan2
- CEP164 | c.3564G>C p.K1188N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV54038683; called by muse, mutect2, varscan2
- CMYA5 | c.10788G>A p.M3596I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV101484362; called by muse, mutect2
- COG2 | c.2108G>A p.G703E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV64186041; called by muse, mutect2, varscan2
- CRYBA4 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.674); catalogued as rs148346157, COSV61322366; called by muse, mutect2, varscan2
- DCLK2 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1436081098, COSV56200006, COSV56213339; called by muse, mutect2, varscan2
- DIAPH2 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61261300, COSV61263823; called by muse, mutect2, varscan2
- DNASE1L1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1457884365, COSV50010017; called by muse, mutect2, varscan2
- ENO1 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.083); catalogued as rs527568599, COSV52302874; called by muse, mutect2, varscan2
- EVPL | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101648801; called by muse, mutect2
- FAF1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.164); catalogued as COSV65636677; called by muse, mutect2, varscan2
- FAM161B | c.730G>A p.E244K (on ENST00000651776; = p.E181K on NM_152445.3) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371012373; called by muse, mutect2, varscan2
- FBXL5 | c.2066C>G p.S689C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58009861; called by muse, mutect2, varscan2
- FLG | c.10496C>G p.S3499C | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64237375; called by muse, mutect2, varscan2
- FLG | c.9800C>T p.S3267F | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64237381; called by muse, mutect2, varscan2
- GABBR1 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63541025; called by muse, mutect2, varscan2
- GFRA1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV62602559; called by muse, mutect2, varscan2
- GON4L | c.3727C>T p.Q1243* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV55187758; called by muse, mutect2, varscan2
- GPR85 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.028); catalogued as rs756442417, COSV51782887; called by muse, mutect2, varscan2
- GPRASP2 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59990388; called by muse, mutect2, varscan2
- GTDC1 | c.27C>G p.F9L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53988754, COSV54001074; called by muse, mutect2, varscan2
- HES4 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59241929; called by muse, mutect2, varscan2
- HS3ST3B1 | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV62906108; called by muse, mutect2
- IL17RB | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 9/136 reads (7%) | catalogued as COSV55474393; called by muse, mutect2
- IMPG2 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV51973990; called by muse, mutect2, varscan2
- INIP | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV65295132; called by muse, mutect2, varscan2
- KIF2B | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs371085430, COSV52127441; called by muse, mutect2
- KIF3B | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65226915; called by muse, mutect2
- KIF5C | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV101276191, COSV68479965; called by muse, mutect2, varscan2
- KMT2C | c.14365C>T p.R4789* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV51326172; called by muse, mutect2, varscan2
- KRT222 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1186891871, COSV67497791; called by muse, mutect2, varscan2
- KRTAP4-1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs369645187; called by muse, mutect2, varscan2
- LRRC7 | c.2533C>T p.R845C (on ENST00000651989 / NM_001370785.2; = p.R812C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1182861744, COSV50414820; called by muse, mutect2, varscan2
- MANSC1 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67110676; called by muse, mutect2, varscan2
- MUC5B | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1210406390, COSV71590280; called by muse, mutect2, varscan2
- MYO15A | c.10283C>T p.A3428V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs773074836, COSV52752468; called by muse, mutect2, varscan2
- MYOF | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as rs200304153, COSV100826110; called by muse, mutect2, varscan2
- NALCN | c.3730A>G p.M1244V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1335260626, COSV99217615; called by muse, mutect2
- NLRC5 | c.3752C>T p.S1251L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV99348218; called by muse, mutect2, varscan2
- OR4K1 | c.7C>A p.H3N | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53458952; called by muse, mutect2, varscan2
- PCDH17 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs143494894; called by muse, mutect2, varscan2
- PIWIL3 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs781034224, COSV59993780; called by muse, mutect2, varscan2
- POF1B | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV99427399, COSV99427766; called by muse, mutect2
- PROCA1 | c.714G>C p.K238N (on ENST00000439862 / NM_001366301.1; = p.K210N on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56385388, COSV56385402; called by muse, mutect2, varscan2
- PROM2 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs553459907, COSV58296835; called by muse, mutect2, varscan2
- RAPGEF2 | c.4058C>A p.S1353Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.392); catalogued as COSV52425144; called by muse, mutect2, varscan2
- SCARB2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs375205937; called by muse, mutect2, varscan2
- SEMA3C | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99542739; called by muse, mutect2
- SLC38A4 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1218992058, COSV56965260; called by muse, mutect2
- SLC6A2 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.251); catalogued as COSV54913845; called by muse, mutect2
- SPATA31D1 | c.2154A>T p.K718N | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.113); catalogued as rs769216202, COSV61193199; called by muse, mutect2, varscan2
- SPNS1 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs766964284, COSV57953753; called by muse, mutect2, varscan2
- SUPV3L1 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62844682; called by muse, mutect2, varscan2
- TAF1 | c.1886T>G p.M629R (on ENST00000373790 / NM_138923.4; = p.M650R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.561); catalogued as COSV52108129, COSV52115532; called by muse, mutect2, varscan2
- TAF4 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as rs4414752; called by muse, mutect2
- TBC1D16 | c.1682C>G p.T561R | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60475671; called by muse, mutect2, varscan2
- TMEM44 | c.1085C>G p.S362* (on ENST00000392432 / NM_001166305.2; = p.S315* on NM_138399.5) | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV56447509; called by muse, mutect2, varscan2
- TNFSF12-TNFSF13 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV53431646; called by muse, mutect2
- TTN | c.19687G>A p.A6563T (on ENST00000591111; = p.A5636T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | PolyPhen benign (0.001); catalogued as rs753356990, COSV59873924, COSV59891082; ClinVar: not provided; called by muse, mutect2, varscan2
- UBR3 | c.5158G>C p.E1720Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.986); catalogued as COSV55844944, COSV55851580; called by muse, mutect2, varscan2
- UGGT2 | c.3979G>C p.D1327H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV65072588, COSV65075050; called by muse, mutect2, varscan2
- UNC93A | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as rs1452317810, COSV57807101; called by muse, mutect2, varscan2
- WDR33 | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs886293482, COSV59246439; called by muse, mutect2, varscan2
- ZAN | c.5827G>C p.D1943H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61805621, COSV61811403; called by muse, mutect2
- ZDHHC5 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1180799222, COSV99762615; called by muse, mutect2
- GPR179 | c.1816G>A p.D606N (on ENST00000621958; = p.D605N on NM_001004334.4) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H1-2 | c.143dup p.A49Gfs*4 | Frame Shift Ins (INS) | VAF 20/40 reads (50%) | called by mutect2, pindel, varscan2
- OR11G2 | c.318_320del p.F106del | In Frame Del (DEL) | VAF 20/78 reads (26%) | called by pindel, varscan2
- CSTF2 | c.813C>A p.S271= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV63376128; called by muse, mutect2, varscan2
- DAGLB | c.597C>A p.L199= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV51702505; called by muse, mutect2, varscan2
- DSCAM | c.5901C>T p.A1967= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs772161625, COSV68021646, COSV68030295; called by muse, mutect2, varscan2
- FGGY | c.471G>A p.L157= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100365884; called by muse, mutect2, varscan2
- IRF1 | c.165C>T p.F55= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV55376135; called by muse, mutect2, varscan2
- KCNQ3 | c.2346C>T p.I782= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV66464312; called by muse, mutect2, varscan2
- KIAA1109 | c.4689C>A p.L1563= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99175264; called by muse, mutect2, varscan2
- LCE2B | c.240C>T p.L80= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs1159206806, COSV64227416; called by muse, mutect2, varscan2
- MC2R | c.525G>T p.V175= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV59617130; called by muse, mutect2, varscan2
- OR1Q1 | c.504C>T p.F168= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs1391526885, COSV52917349; called by muse, mutect2, varscan2
- PCDHB16 | c.2157G>A p.A719= | Silent (SNP) | VAF 8/237 reads (3%) | catalogued as rs781822956, COSV53362338; called by muse, mutect2
- PCDHGA4 | c.2358C>T p.H786= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs760807195, COSV53905353; called by muse, mutect2, varscan2
- PHLDA3 | c.360C>T p.L120= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs754158710, COSV66210697; called by muse, mutect2, varscan2
- PHLDA3 | c.174C>T p.I58= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs371751537; called by muse, mutect2, varscan2
- PJA1 | c.1860G>A p.P620= (on ENST00000361478 / NM_145119.4; = p.P432= on NM_022368.5) | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV64052698; called by muse, mutect2, varscan2
- PPARGC1B | c.1563G>A p.E521= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs751911211, COSV100495167; called by muse, mutect2
- PSTPIP1 | c.102G>A p.K34= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV51198333, COSV51199500; called by muse, mutect2, varscan2
- RPGRIP1 | c.315G>A p.Q105= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV52845571; called by muse, mutect2, varscan2
- RUBCN | c.1425C>T p.I475= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs781500046, COSV99585064; called by muse, mutect2, varscan2
- SIPA1L2 | c.2442G>A p.E814= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as rs990578000, COSV99479653; called by muse, mutect2
- SLC18A1 | c.384C>T p.G128= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV52346877; called by muse, mutect2, varscan2
- SMAD6 | c.1017C>T p.H339= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV56593567; called by muse, mutect2, varscan2
- SYT3 | c.1428C>T p.I476= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs1254945848, COSV58895598; called by muse, mutect2, varscan2
- TAF7 | c.1008C>T p.L336= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100515065; called by muse, mutect2, varscan2
- TAS2R50 | c.34C>T p.L12= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1487513862, COSV67852975, COSV67863268; called by muse, varscan2
- TEX13A | c.717G>A p.E239= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV61144104; called by muse, mutect2, varscan2
- TRAV14DV4 | c.24G>A p.K8= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs772462292; called by mutect2, varscan2
- ZNF680 | c.1551C>T p.L517= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV59014086; called by muse, mutect2, varscan2
- ZNF93 | c.105G>A p.E35= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV59374187; called by muse, mutect2, varscan2
- ZSCAN5B | c.675G>A p.L225= | Silent (SNP) | VAF 64/204 reads (31%) | catalogued as COSV62838428; called by muse, mutect2, varscan2
- TIPIN | c.475+1775C>T | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as COSV56019339, COSV99972386; called by muse, mutect2, varscan2
- UBTFL2 | n.505C>A | RNA (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
